Somatic mutation profile of tumor specimen ALCH-B4UC-TTP1-A (aliquot ALCH-B4UC-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4UC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.7 years (22,919 days).
Specimen ALCH-B4UC-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea294f8e-2ccf-48be-b2fd-fa8c10aab394.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4UC-NB1-A (Blood Derived Normal), aliquot ALCH-B4UC-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b63b8a9d-bf76-4b62-a04c-f0472bbc4dd0

The open-access MAF lists 35 somatic variants for this specimen: 25 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 7, 5'UTR 1, Nonstop Mutation 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR2B | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV100754184; called by muse, mutect2
- AGTR2 | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs1468172864, COSV64156140; called by muse, mutect2, varscan2
- AP001458.2 | c.299G>T p.*100Lext*3 | Nonstop Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as rs139005370; called by muse, mutect2, varscan2
- BEST3 | c.1948G>A p.D650N | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); catalogued as rs1177884465, COSV58301716; called by muse, mutect2, varscan2
- HYDIN | c.8077G>A p.E2693K | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as rs374866149, COSV59271323; called by muse, mutect2, varscan2
- IFIH1 | c.2937G>T p.L979F | Missense Mutation (SNP) | VAF 31/284 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.174); catalogued as rs372007025; called by muse, mutect2, varscan2
- MYO1C | c.2464C>T p.R822W (on ENST00000648651 / NM_001080779.2; = p.R787W on NM_033375.5) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs763305296; called by muse, mutect2
- NOL6 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs369599517; called by muse, mutect2, varscan2
- PRR33 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs530281752; called by muse, varscan2
- TRA2A | c.640C>T p.H214Y | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.84); PolyPhen benign (0.006); catalogued as rs1280625191, COSV51716646; called by muse, mutect2, varscan2
- UQCR11 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.259); catalogued as COSV73977267; called by muse, mutect2, varscan2
- AGGF1 | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); called by muse, mutect2
- ARSK | c.259A>G p.M87V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); called by muse, mutect2
- BRWD3 | c.3288G>T p.K1096N | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.411); called by muse, mutect2
- CEP72 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRISP1 | c.627C>G p.N209K | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DMD | c.10931A>T p.D3644V | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- DOCK11 | c.2344C>A p.P782T | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DRC1 | c.526A>C p.S176R | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.807); called by muse, mutect2
- HDAC3 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGSF10 | c.6889A>G p.T2297A | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INSYN1 | c.739A>G p.S247G | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- PFDN6 | c.70A>C p.S24R | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- TET1 | c.346T>A p.S116T | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZNF23 | c.1520A>C p.K507T | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- COQ8B | c.933C>T p.A311= | Silent (SNP) | VAF 16/113 reads (14%) | catalogued as rs377625253; called by muse, mutect2, varscan2
- CRNKL1 | c.354C>A p.V118= | Silent (SNP) | VAF 12/246 reads (5%) | catalogued as COSV55631920; called by muse, mutect2
- DNMBP | c.1737C>T p.I579= | Silent (SNP) | VAF 17/105 reads (16%) | called by muse, mutect2, varscan2
- DTL | c.666C>T p.V222= | Silent (SNP) | VAF 35/255 reads (14%) | called by muse, mutect2, varscan2
- LILRB3 | c.1317C>T p.L439= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as rs112492538; called by muse, mutect2
- PHF12 | c.2301A>G p.Q767= | Silent (SNP) | VAF 23/128 reads (18%) | catalogued as rs1035356853; called by muse, mutect2, varscan2
- STIM1 | c.1266A>G p.A422= | Silent (SNP) | VAF 21/228 reads (9%) | called by muse, mutect2
- ARHGAP22 | c.-15G>A | 5'UTR (SNP) | VAF 11/111 reads (10%) | catalogued as rs372132308; called by muse, mutect2, varscan2
- NAV3 | c.2024-12876C>A | Intron (SNP) | VAF 27/96 reads (28%) | called by muse, mutect2, varscan2
- ZNF849P | n.789G>T | RNA (SNP) | VAF 16/121 reads (13%) | called by muse, mutect2, varscan2
